Somatic mutation profile of tumor specimen TCGA-E8-A436-01A (aliquot TCGA-E8-A436-01A-12D-A23U-08) from TCGA case TCGA-E8-A436, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 53.8 years (19,640 days).
Specimen TCGA-E8-A436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcc6d0bd-f3bc-463d-ae01-a2af2cf7b591.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A436-10A (Blood Derived Normal), aliquot TCGA-E8-A436-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38dd7655-de14-4f98-9921-58da3863e7e5

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AK7 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50873747; called by muse, mutect2, varscan2
- CSMD2 | c.5626A>G p.N1876D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53923839; called by muse, mutect2, varscan2
- DRD4 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51562582; called by muse, mutect2
- HCAR3 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63672577; called by muse, mutect2, varscan2
- OR5L1 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs748230944, COSV61734356, COSV61735346; called by muse, mutect2, varscan2
- RGL1 | c.539C>T p.P180L (on ENST00000360851 / NM_001297672.2; = p.P215L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs766067914, COSV58987938; called by muse, mutect2
- SFI1 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101192048; called by muse, varscan2
- FAAH | c.285C>G p.A95= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV54544040, COSV54544512; called by muse, mutect2
- LRRC4B | c.915C>T p.R305= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs372018089; called by muse, mutect2, varscan2
- MKRN1 | c.1029A>T p.P343= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55437355; called by muse, mutect2, varscan2
- TRPM2 | c.2124G>A p.V708= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV55971503; called by muse, mutect2, varscan2
- WLS | c.729C>T p.P243= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52042935, COSV99258891; called by muse, mutect2, varscan2
- P4HTM | c.1073+86C>G | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as COSV59087688; called by muse, mutect2, varscan2
